Somatic mutation profile of tumor specimen TCGA-19-2620-01A (aliquot TCGA-19-2620-01A-01W-0922-08) from TCGA case TCGA-19-2620, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.3 years (25,665 days).
Specimen TCGA-19-2620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f0de2e1-6c31-411e-93b9-aa279ed7bdb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2620-10A (Blood Derived Normal), aliquot TCGA-19-2620-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7abc238e-2980-4638-98be-11df3ea12736

The open-access MAF lists 115 somatic variants for this specimen: 83 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 28, Nonsense Mutation 10, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, Splice Site 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 327/1894 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 17/156 reads (11%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- PTPN11 | c.1530G>C p.Q510H | Missense Mutation (SNP) | VAF 344/1796 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs397507550, CM117756, COSV61005626, COSV61006865; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCC11 | c.2922del p.F974Lfs*5 | Frame Shift Del (DEL) | VAF 22/194 reads (11%) | catalogued as COSV62324969; called by mutect2, varscan2
- ADAMTS20 | c.2437C>T p.R813* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV67132463; called by muse, varscan2
- ADGRD1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs535355861, COSV55439160; called by muse, mutect2, varscan2
- AHNAK2 | c.6842T>A p.L2281Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779244499, COSV60927905; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.3943G>A p.G1315R | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV51851544; called by muse, mutect2, varscan2
- APBB1IP | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs773115126; called by muse, mutect2, varscan2
- AS3MT | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.839); catalogued as rs756399134, COSV54917639; called by muse, mutect2, varscan2
- BCHE | c.107C>A p.T36K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52256885; called by muse, mutect2, varscan2
- CACNA2D1 | c.2411G>A p.G804E (on ENST00000356253 / NM_001366867.1; = p.G792E on NM_000722.4) | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV62383564; called by muse, mutect2, varscan2
- CCDC158 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 127/301 reads (42%) | catalogued as rs755862671, COSV66356514; called by muse, mutect2, varscan2
- CDH9 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV50322416; called by muse, mutect2, varscan2
- CHMP4C | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.164); catalogued as COSV51927755; called by muse, mutect2, varscan2
- COL27A1 | c.4844dup p.P1617Sfs*12 | Frame Shift Ins (INS) | VAF 2/19 reads (11%) | catalogued as rs758820969; called by pindel, varscan2
- DNAH10 | c.9742G>A p.V3248M (on ENST00000409039; = p.V3187M on NM_207437.3) | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571654959, COSV68996371; called by muse, mutect2, varscan2
- DNAH7 | c.4339C>G p.L1447V | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56772316; called by muse, mutect2, varscan2
- ELSPBP1 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs758594292, COSV60413856; called by muse, mutect2
- ENPP5 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751242857, COSV57909145; called by muse, mutect2, varscan2
- EPHA7 | c.2611G>C p.D871H | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.674); catalogued as COSV65186253; called by muse, mutect2, varscan2
- FBXL16 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV60964915; called by muse, mutect2, varscan2
- GABRA6 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs145469537, COSV50878218, COSV50884934; called by muse, mutect2
- GHSR | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs121917883, CM061011, COSV53840296; called by muse, mutect2, varscan2
- HMCN1 | c.8776C>T p.R2926* | Nonsense Mutation (SNP) | VAF 70/226 reads (31%) | catalogued as rs142475663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF2BP1 | c.911A>C p.Q304P | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV51733041; called by muse, mutect2, varscan2
- IGHV3-7 | c.155G>A p.W52* | Nonsense Mutation (SNP) | VAF 389/1391 reads (28%) | catalogued as rs782787393; called by muse, mutect2
- IL1RL1 | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 116/263 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV52117911; called by muse, mutect2, varscan2
- LAMA1 | c.4417G>A p.D1473N | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as rs756779273, COSV67537471; called by muse, mutect2, varscan2
- LARP1 | c.2792T>A p.M931K (on ENST00000518297 / NM_033551.3; = p.M854K on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV60428579; called by muse, mutect2
- LGSN | c.402A>T p.E134D | Missense Mutation (SNP) | VAF 130/215 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); catalogued as COSV65727663; called by muse, mutect2, varscan2
- LILRA2 | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754558055; called by muse, mutect2
- LPIN1 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 115/489 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs375865167; called by muse, mutect2, varscan2
- LRP2 | c.6283C>T p.R2095* | Nonsense Mutation (SNP) | VAF 31/68 reads (46%) | catalogued as rs753549113, COSV55544116; called by muse, mutect2, varscan2
- LRRC8B | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV58375842; called by muse, mutect2, varscan2
- MAN1A1 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV63783394; called by muse, mutect2, varscan2
- MAP3K4 | c.730A>G p.R244G | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as COSV62335445; called by muse, mutect2, varscan2
- MDGA2 | c.2218T>C p.Y740H (on ENST00000399232 / NM_001113498.2; = p.Y442H on NM_182830.4) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62100319; called by muse, mutect2, varscan2
- MICAL1 | c.1653G>T p.Q551H | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV57805152; called by muse, mutect2
- MYO10 | c.5954G>A p.R1985H | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369799275; called by muse, mutect2, varscan2
- NPHS1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as COSV100799592; called by muse, mutect2, varscan2
- NTAQ1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs767518368, COSV54874302; called by muse, mutect2, varscan2
- OR1D2 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV58921900, COSV58921937; called by muse, mutect2
- OR5D18 | c.340T>A p.F114I | Missense Mutation (SNP) | VAF 231/873 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV61736553, COSV61739035; called by muse, mutect2, varscan2
- OR5H2 | c.193T>A p.Y65N | Missense Mutation (SNP) | VAF 167/524 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62350752, COSV62351215; called by muse, mutect2, varscan2
- OR5H2 | c.697A>C p.K233Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV62351229; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.679C>T p.R227C (on ENST00000259318 / NM_001136562.3; = p.R458C on NM_007203.5) | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs765001694, COSV52178386; called by muse, varscan2
- PMPCB | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201686193; called by muse, mutect2
- RIOK3 | c.179+1G>A p.X60_splice | Splice Site (SNP) | VAF 40/126 reads (32%) | catalogued as rs373422920; called by muse, mutect2, varscan2
- RUBCN | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56366969; called by muse, mutect2, varscan2
- SDK2 | c.2002G>A p.V668I | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs754435436, COSV66190084; called by muse, mutect2, varscan2
- SEC31A | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as COSV58876271; called by muse, mutect2, varscan2
- SLC45A4 | c.1478C>T p.T493M (on ENST00000517878 / NM_001286646.2; = p.T442M on NM_001080431.2) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs764827415, COSV50145421; called by muse, mutect2
- SLCO2A1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761212094, COSV60487022; called by muse, mutect2, varscan2
- SORBS2 | c.299C>T p.T100M (on ENST00000284776 / NM_021069.5; = p.T146M on NM_003603.6) | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752881456; called by muse, mutect2
- SPTBN2 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 18/651 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59462334; called by muse, mutect2
- SYNE2 | c.19737G>A p.M6579I | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV59956727; called by muse, mutect2, varscan2
- TAF1L | c.1968A>T p.Q656H | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV54264184; called by muse, mutect2
- TRAF3IP3 | c.1520A>T p.H507L | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV50554879, COSV50558264; called by muse, mutect2, varscan2
- TRPM1 | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs372226363; called by muse, mutect2
- WNT9B | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs566511950, COSV51519014; called by muse, mutect2, varscan2
- ZNF189 | c.20dup p.P8Afs*10 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | catalogued as rs745895168; called by mutect2, pindel
- ANGPT2 | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ATG16L1 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- CTSC | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- DXO | c.812+1G>A p.X271_splice | Splice Site (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- FAM234B | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 106/1486 reads (7%) | called by muse, mutect2
- FCGBP | c.10822C>T p.P3608S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LYSMD4 | c.166C>A p.H56N (on ENST00000409796 / NM_001284417.2; = p.A26= on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- MED23 | c.1145del p.G382Efs*8 | Frame Shift Del (DEL) | VAF 43/120 reads (36%) | called by mutect2, pindel, varscan2
- MRPL45 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 18/564 reads (3%) | called by muse, mutect2
- PPFIBP2 | c.2175G>T p.E725D | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- PSMD1 | c.1909G>A p.V637I | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PTGFRN | c.2487C>A p.F829L | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.076); called by muse, mutect2
- RIBC2 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | called by muse, varscan2
- SEC31A | c.3552A>T p.E1184D (on ENST00000355196 / NM_001318120.1; = p.E1145D on NM_016211.4) | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- STS | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TDRD5 | c.2554C>A p.L852I | Missense Mutation (SNP) | VAF 22/445 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.265); called by muse, mutect2
- TMEM132B | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- TNPO1 | c.1937A>C p.K646T | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- TNRC6A | c.2149G>A p.V717I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF544 | c.1072C>A p.Q358K | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF783 | c.267del p.N90Tfs*54 | Frame Shift Del (DEL) | VAF 40/189 reads (21%) | called by mutect2, pindel, varscan2
- ACRV1 | c.747G>A p.T249= | Silent (SNP) | VAF 199/633 reads (31%) | catalogued as rs370037825; called by muse, mutect2, varscan2
- ARMCX2 | c.1233G>T p.L411= | Silent (SNP) | VAF 72/385 reads (19%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.828C>T p.S276= | Silent (SNP) | VAF 64/169 reads (38%) | catalogued as rs750756456, COSV57541889, COSV57543432; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL2A1 | c.2730C>A p.S910= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- DISP3 | c.1002G>A p.S334= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53823479; called by muse, mutect2, varscan2
- ECT2L | c.1254G>A p.T418= | Silent (SNP) | VAF 65/453 reads (14%) | catalogued as rs750706600, COSV62885596; called by muse, mutect2, varscan2
- FLG | c.3843C>T p.D1281= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as rs545397624, COSV64242640; called by muse, mutect2, varscan2
- GP2 | c.1314C>A p.S438= (on ENST00000381362 / NM_001007240.3; = p.S435= on NM_001502.4) | Silent (SNP) | VAF 58/170 reads (34%) | catalogued as COSV56894984; called by muse, mutect2, varscan2
- GPR61 | c.396G>A p.S132= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs747436555, COSV68177797; called by muse, mutect2, varscan2
- GRPEL1 | c.420C>T p.L140= | Silent (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- H1-7 | c.75G>A p.A25= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV58602473; called by muse, mutect2, varscan2
- KLHL13 | c.894G>A p.T298= | Silent (SNP) | VAF 49/167 reads (29%) | catalogued as rs377195610, COSV53249323, COSV53249754; called by muse, mutect2, varscan2
- LARP1 | c.2790G>A p.K930= (on ENST00000518297 / NM_033551.3; = p.K853= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 41/186 reads (22%) | catalogued as COSV60428563; called by muse, mutect2
- NFX1 | c.1965C>T p.R655= | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- NPC1L1 | c.747C>T p.D249= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs148698796; called by muse, mutect2, varscan2
- OR5H1 | c.60A>G p.Q20= | Silent (SNP) | VAF 104/420 reads (25%) | catalogued as COSV99075115; called by muse, mutect2, varscan2
- OR7A10 | c.348C>T p.T116= | Silent (SNP) | VAF 50/268 reads (19%) | catalogued as rs757173899, COSV50166156; called by muse, mutect2, varscan2
- PCDH18 | c.1320G>A p.R440= | Silent (SNP) | VAF 52/218 reads (24%) | catalogued as rs753591659, COSV61267620; called by muse, mutect2, varscan2
- PCDHA4 | c.1914C>T p.D638= | Silent (SNP) | VAF 45/238 reads (19%) | catalogued as rs781864694, COSV63539551; called by muse, mutect2, varscan2
- PLEKHG4B | c.2700C>T p.N900= (on ENST00000283426; = p.N1256= on NM_052909.5) | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- PTPN5 | c.117G>A p.V39= | Silent (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- RNF185 | c.534C>T p.F178= | Silent (SNP) | VAF 37/189 reads (20%) | called by muse, mutect2, varscan2
- RPL7A | c.621G>T p.V207= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as COSV59299388; called by muse, mutect2
- TM4SF4 | c.564G>T p.G188= | Silent (SNP) | VAF 36/318 reads (11%) | catalogued as COSV59515133; called by muse, mutect2, varscan2
- TRAV9-2 | c.189A>G p.L63= | Silent (SNP) | VAF 13/404 reads (3%) | catalogued as rs1026568905; called by muse, mutect2
- TRPM8 | c.24C>A p.L8= | Silent (SNP) | VAF 14/412 reads (3%) | catalogued as COSV61222659; called by muse, mutect2
- TTF2 | c.852G>A p.E284= | Silent (SNP) | VAF 71/312 reads (23%) | catalogued as COSV65632988; called by muse, mutect2, varscan2
- UPF1 | c.1584G>A p.V528= (on ENST00000599848 / NM_001297549.2; = p.V517= on NM_002911.4) | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- ANKRD20A5P | n.291C>T | RNA (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- FER1L6 | c.-2G>A | 5'UTR (SNP) | VAF 9/32 reads (28%) | catalogued as rs879049057, COSV101206024; called by muse, mutect2, varscan2
- GOSR2 | c.282+2917T>C | Intron (SNP) | VAF 79/319 reads (25%) | called by muse, mutect2, varscan2
- TFPI | c.628+5358G>A | Intron (SNP) | VAF 33/83 reads (40%) | catalogued as rs149480203; called by muse, mutect2, varscan2
